Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E6, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E6-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODE:
One lymph node, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Four lymph nodes, no tumor present.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

path ICD-O-3
Adenocarcinoma NOS 8140/3
CCF Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
JW 5/21/13

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODE – The specimen consists of a segment of fibrofatty tissue measuring 6.0 x 3.0 x 1.0 cm. Embedded within the tissue is a lymph node measuring 1.0 x 1.0 x 0.3 cm. The entire lymph node is submitted for frozen section diagnosis.

SECTION CODE: A1, A2, one lymph node bisected.

*FS/DX: NEGATIVE FOR CARCINOMA.

(B) LEFT PELVIC LYMPH NODES - A portion of red-tan adipose tissue (7.2 x 3.5 x 1.5 cm). Specimen is serially sectioned. Four possible lymph nodes are identified ranging in size from 0.3 x 0.2 x 0.2 to 3.2 x 1.0 x 0.6 cm.

SECTION CODE: B1, two possible lymph nodes; B2, one lymph node, bisected; B3, B4, one lymph node, bisected.

(C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

Released by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

Addendum completed by

ADDENDUM

DIAGNOSIS:

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5).

(SEE COMMENT).

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE. (SEE COMMENT)

Margins of resection free of tumor but carcinoma extending focally to < 0.1mm from the margin of resection.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa differentia, no tumor present.

COMMENT

The prostate gland contains three separate foci of prostatic adenocarcinoma. All tumor foci are located in the peripheral zone. The dominant tumor focus is located in the right anterolateral, right lateral, right posterolateral and mid posterior peripheral zone. This tumor focus measures 2.0 x 1.8 cm in the largest cross sectional dimension and it is present in the three cross sections of the prostate and extensively in the apex and base regions. This tumor focus exhibits in the right posterolateral aspect of the prostate, right superior neurovascular bundle region and bladder neck region, extension into extraprostatic adipose tissue. The added length of extraprostatic tumor is 26.0 mm. The margin of resection is free of tumor but tumor extends focally (right apex) to less than 0.1 mm from the inked margin of resection. The second largest tumor focus is located in the left anterolateral and left lateral peripheral zone. This tumor focus measures 0.4 x 0.3 cm in the largest cross sectional dimension and it is present in two cross sections and focally in the apical region. The third tumor focus is located in the left posterior peripheral zone. This tumor focus measures 0.4 x 0.3 cm in the largest cross sectional dimension and it is present in two cross sections. The non-dominant tumor foci are of lower histologic grade (Gleason score 6) and are confined to the prostate.

The dominant tumor focus exhibits Gleason grade 3, 4, and 5. The Gleason grade 5 component is located predominantly in the right lateral and right anterolateral aspect of the tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa differentia.

The prostate gland (6.4 x 3.3 x 3.5 cm, 49 grams, post fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. Tumor is palpated in the right posterolateral aspect of the prostate from the apex to the base. Serial cross sections have post fixation demonstrating a firm area in the right peripheral zone of the three cross sections of the prostate.

The seminal vesicles and segments of vasa differentia are grossly free of tumor.

SECTION CODE: C1-C4, right seminal vesicle and segment of right vas deferens from the base towards the tip; C5-C7, left seminal vesicle and segment of left vas deferens from the base towards the tip; C8, prostatic base right border; C9-C11, prostatic base right posterior border; C12-C16, prostatic base central portion; C17, prostatic base left border; C18, C19, prostatic base left posterior border; C20-C22, apex anterior; C23, C24, apex left; C25, C26, apex posterior; C27, C28, apex right; C29-C42, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (C5) denotes surfaces which do not represent the true margin of resection. Multiple blocks (C31, C32, C36, C37, C41,

[page 3 of 3]
[REDACTED]
[REDACTED]
Specimen Date/Time:

and C42) submitted for decalcification.

Released by:

-----END OF REPORT-----

HI/AA Discrepancy		/
Qual/Synch/Anous Primary Listed		/

Source: NCI Genomic Data Commons file 0b7b035e-9700-40d4-82ff-e891778e8a27 (TCGA-KK-A6E6.C67B882A-02B1-4511-B55C-87A33FC3E73E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).